Gene-level copy-number profile of tumor specimen TCGA-CH-5788-01A from TCGA case TCGA-CH-5788, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.1 years (25,233 days).
Specimen TCGA-CH-5788-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.82404b91-a977-4f15-8bdf-dcd31ec1fa6c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5788-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/190e7c95-6461-43b4-ac1e-aed50e5b3b49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 9,152; copy number 2: 42,694; copy number 3: 7,058; copy number 4: 209; copy number 5: 576; copy number 6: 73; copy number 10: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5788-01A-11D-1574-01): tumor purity 0.84, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:138,307,319–140,221,485, 25 genes: IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,234,923, 1 gene: AC092156.1.
- chr5:98,025,965–98,026,139, 1 gene: AC008834.1.
- chr5:98,853,985–98,929,007, 2 genes (within-gene range 0–2): CHD1, RNU6-402P.
- chr6:75,928,513–75,928,625, 1 gene: Y_RNA.
- chr13:67,577,624–67,832,827, 3 genes (within-gene range 0–1): AL512452.1, BCRP9, NPM1P22.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 671 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:3,264,032–37,449,249, 576 genes, copy number 5 (broad region; genes not listed).
- chr7:38,253,380–38,318,861, 11 genes, copy number 6: TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr8:36,887,456–40,016,391, 84 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,769. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
